Gene-level copy-number profile of tumor specimen HTMCP-03-06-02057-01B from CGCI case HTMCP-03-06-02057, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 45.5 years (16,612 days).
Specimen HTMCP-03-06-02057-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 94d6d62f-e3f4-4bd9-a515-0902b6df6de6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02057-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/408596e6-d8d0-448d-ad48-9e3e571a0a27

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 2,413; copy number 2: 46,368; copy number 3: 6,659; copy number 4: 2,237; copy number 5: 56; copy number 6: 293; copy number 7: 323; copy number 9: 1; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:86,889,569–87,845,612, 39 genes (within-gene range 0–1): RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P.
- chr16:71,080,866–71,093,667, 1 gene (within-gene range 0–2): AC138625.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 675 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–90,261,708, 1 gene, copy number 5: HSPE1P19.
- chr3:120,908,072–122,639,047, 33 genes, copy number 5: STXBP5L, AC072026.1, MIR5682, AC078857.1, AC079841.1, AC079841.2, POLQ, RPL7AP11, ARGFX, FBXO40, HCLS1, RN7SL172P, RNU4-62P, GOLGB1, IQCB1, EAF2, SLC15A2, ILDR1, Y_RNA, CD86, CASR, HNRNPA1P23, CSTA, CCDC58, FAM162A, WDR5B, AC083798.2, AC083798.1, KPNA1, AC096861.1, PARP9, DTX3L, PARP15.
- chr3:135,959,275–137,011,085, 22 genes, copy number 5: NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1.
- chr3:138,652,698–138,889,957, 5 genes, copy number 6: PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3.
- chr5:58,198–41,071,342, 606 genes, copy number 6–9 (broad region; genes not listed).
- chr9:40,481,558–40,642,117, 6 genes, copy number 6: AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2.
- chr9:63,111,255–63,143,401, 2 genes, copy number 10: AL591379.1, AQP7P4.

Autosomal genes at a single copy (total copy number 1): 2,413. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
